Somatic mutation profile of tumor specimen C3L-02900-01 (aliquot CPT0218670006) from CPTAC case C3L-02900, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.9 years (19,332 days).
Specimen C3L-02900-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ae5518e-28dc-4d5b-8ace-1b1c36730730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02900-31 (Blood Derived Normal), aliquot CPT0219910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ffb651a-de5a-43a1-a576-fe13fbdefadc

The open-access MAF lists 74 somatic variants for this specimen: 53 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Intron 3, RNA 2, Frame Shift Del 1, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/123 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 180/233 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FSHR | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1418661302; called by muse, mutect2, varscan2
- GOLGA4 | c.2191C>G p.H731D | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62712107; called by muse, mutect2
- GRIP2 | c.3274C>T p.R1092C (on ENST00000619221; = p.R995C on NM_001080423.4) | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759209816, COSV56119423; called by muse, mutect2, varscan2
- LONRF3 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs978444093; called by muse, mutect2
- LRFN3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs370578308; called by muse, mutect2, varscan2
- MAP3K8 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV53922161; called by muse, mutect2
- MSR1 | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1348673851; called by muse, mutect2, varscan2
- OR8H1 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100476898; called by muse, mutect2
- RGS9 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1355428022, COSV99287433; called by muse, mutect2, varscan2
- RTCA | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV53119486; called by muse, mutect2, varscan2
- STARD3 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473199967, COSV100302695; called by muse, mutect2
- SYTL2 | c.2278G>T p.A760S (on ENST00000528231 / NM_001162951.2; = p.A736S on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV100314201; called by muse, mutect2, varscan2
- TIGD3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760820136, COSV52891012; called by muse, mutect2
- ZNF91 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); catalogued as COSV56083447; called by muse, mutect2, varscan2
- ADGRL2 | c.525G>C p.W175C | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD30A | c.3436C>T p.L1146F (on ENST00000611781; = p.L1090F on NM_052997.2) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANXA6 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ARHGAP40 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATRX | c.6498_6501delinsG p.A2167del | In Frame Del (DEL) | VAF 16/24 reads (67%) | called by pindel, varscan2*
- C14orf119 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CABS1 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC20 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CHDH | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CRISP2 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTAG2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CXCL2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DOP1B | c.6375A>C p.R2125S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.024); called by mutect2, varscan2
- EGFL7 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ELAC2 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 165/425 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM193B | c.2364C>G p.Y788* | Nonsense Mutation (SNP) | VAF 21/192 reads (11%) | called by muse, mutect2, varscan2
- FER1L6 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GOLGA6L6 | c.2091G>T p.E697D | Missense Mutation (SNP) | VAF 48/698 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2
- HECW2 | c.2796del p.V933Cfs*18 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- IGF2BP3 | c.1544A>C p.N515T | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- IL31RA | c.684A>C p.E228D | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); called by muse, mutect2
- KCNC2 | c.1721C>A p.T574K | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KYNU | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MAGI2 | c.4267C>G p.P1423A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP7 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYOD1 | c.67T>G p.F23V | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NAPB | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NDUFA11 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 73/493 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NHS | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- OR10H4 | c.193T>A p.C65S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- RBM4B | c.991G>C p.A331P | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SLC1A5 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SLC30A8 | c.931A>G p.N311D | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SLFN12 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD15 | c.4478G>C p.G1493A | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- VWA3B | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2
- ZNF804B | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACKR4 | c.498C>T p.I166= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- ADAMTS7 | c.150A>T p.R50= | Silent (SNP) | VAF 132/986 reads (13%) | called by muse, mutect2, varscan2
- DDC | c.1170A>C p.S390= | Silent (SNP) | VAF 117/294 reads (40%) | called by muse, mutect2, varscan2
- DPP10 | c.2364A>C p.L788= | Silent (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- HTR1B | c.843C>T p.S281= | Silent (SNP) | VAF 81/235 reads (34%) | called by muse, mutect2, varscan2
- IL31 | c.459A>G p.K153= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- ITPR1 | c.579A>G p.L193= | Silent (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- KBTBD3 | c.192G>A p.P64= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs73554750, COSV101595692, COSV73241582; called by muse, mutect2, varscan2
- LRRC24 | c.1236G>A p.A412= | Silent (SNP) | VAF 130/237 reads (55%) | catalogued as rs1218535348; called by muse, mutect2, varscan2
- PHACTR3 | c.324C>T p.L108= | Silent (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- RSF1 | c.1524T>C p.P508= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- SLC4A7 | c.1446T>C p.H482= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs1247450908; called by muse, mutect2, varscan2
- TMEM86B | c.21G>A p.G7= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as rs749731094; called by muse, mutect2, varscan2
- UTP18 | c.744T>G p.R248= | Silent (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- ZFHX4 | c.8403T>C p.D2801= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV51493863; called by muse, mutect2, varscan2
- COL4A6 | c.444+50T>C | Intron (SNP) | VAF 50/64 reads (78%) | called by muse, mutect2, varscan2
- EPHA6 | c.2784+10216A>G | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- INCA1 | c.-27A>G | 5'UTR (SNP) | VAF 193/233 reads (83%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1840G>A | RNA (SNP) | VAF 145/471 reads (31%) | catalogued as rs748276592; called by muse, mutect2, varscan2
- OVCH1-AS1 | n.481G>T | RNA (SNP) | VAF 157/428 reads (37%) | called by muse, mutect2, varscan2
- SPCS2 | c.115-1350G>A | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
